Gene-level copy-number profile of tumor specimen TCGA-FA-A4BB-01A from TCGA case TCGA-FA-A4BB, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 67.3 years (24,590 days).
Specimen TCGA-FA-A4BB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.69d65371-5fd2-4988-ad11-c571d5bcc644.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FA-A4BB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a16b709b-a58b-4d40-98dc-e8d7b2ca4c82

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 4,193; copy number 2: 51,686; copy number 3: 3,724; copy number 4: 116; copy number 6: 40; copy number 9: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FA-A4BB-01A-11D-A31W-01): tumor purity 0.23, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,040,594–22,495,966, 59 genes: TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:59,208,510–59,214,699, 2 genes, copy number 9: MPEG1, RN7SL42P.

Autosomal genes at a single copy (total copy number 1): 1,812. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
